Somatic mutation profile of tumor specimen ALCH-B2T4-TTP1-A (aliquot ALCH-B2T4-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2T4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.1 years (22,315 days).
Specimen ALCH-B2T4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b7938b8-8262-420d-8db8-4d7cec61a544.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2T4-NB1-A (Blood Derived Normal), aliquot ALCH-B2T4-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1131f359-3f6b-4f60-9407-1bda198e9083

The open-access MAF lists 263 somatic variants for this specimen: 162 protein-altering or splice-affecting, 61 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 61, Intron 16, RNA 11, Nonsense Mutation 11, 3'UTR 5, 5'UTR 5, Frame Shift Del 5, Splice Site 4, Frame Shift Ins 3, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 126/336 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs371124726; called by muse, mutect2, varscan2
- ACACB | c.6599G>T p.R2200L | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58136128; called by muse, mutect2
- ADAM33 | c.1435A>G p.M479V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1363182148; called by muse, mutect2, varscan2
- AK9 | c.5086G>A p.A1696T | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69853366, COSV69853872; called by muse, mutect2, varscan2
- ANO4 | c.212C>T p.P71L (on ENST00000392977 / NM_001286615.2; = p.P36L on NM_178826.4) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs267603739; called by muse, mutect2, varscan2
- ATAD3A | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV59234070; called by mutect2, varscan2
- ATAD3B | c.324+1G>T p.X108_splice (on ENST00000308647; = p.V163L on NM_031921.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 27/42 reads (64%) | catalogued as COSV58019634; called by mutect2, varscan2
- BMPR2 | c.2900C>G p.S967* | Nonsense Mutation (SNP) | VAF 12/257 reads (5%) | catalogued as COSV65812548; called by muse, mutect2
- CADM1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 65/306 reads (21%) | catalogued as COSV100523521; called by muse, mutect2, varscan2
- CCDC7 | c.3880C>A p.P1294T | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.925); catalogued as rs947278709; called by muse, mutect2, varscan2
- CCDC88A | c.4745-8dup | Splice Region (INS) | VAF 58/218 reads (27%) | catalogued as rs1258447478; called by pindel, varscan2
- CDK5RAP2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 179/650 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs13287734; called by muse, varscan2
- CDKN2A | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 49/109 reads (45%) | catalogued as COSV58705987; called by muse, mutect2, varscan2
- CHRND | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147919651, COSV51330303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLPTM1L | c.1513G>T p.V505F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as rs1439283017; called by muse, mutect2, varscan2
- CSMD1 | c.9852C>G p.H3284Q (on ENST00000520002; = p.H3283Q on NM_033225.6) | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100151662, COSV59340880; called by muse, mutect2, varscan2
- CTAGE6 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 127/1398 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs895689363; called by muse, mutect2
- EHD4 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs150673276; called by muse, mutect2, varscan2
- EVPL | c.4873G>T p.E1625* | Nonsense Mutation (SNP) | VAF 55/160 reads (34%) | catalogued as rs1481705826; called by muse, mutect2, varscan2
- GRIP2 | c.3323C>T p.A1108V (on ENST00000619221; = p.A1011V on NM_001080423.4) | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767047626; called by muse, varscan2
- GSTM4 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 221/561 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs1557951100; called by muse, mutect2, varscan2
- GUCY2C | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148314105; called by muse, mutect2, varscan2
- KRT78 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs746649942; called by muse, mutect2, varscan2
- LOXL2 | c.924C>G p.S308R | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1033058795; called by muse, mutect2, varscan2
- LRP2 | c.7479G>T p.M2493I | Missense Mutation (SNP) | VAF 128/515 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55567887; called by muse, mutect2, varscan2
- LRRC27 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs745330910; called by muse, mutect2
- MED16 | c.1768G>T p.V590F | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as rs913709006, COSV54129321; called by muse, varscan2
- METTL8 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs774209016, COSV64552498; called by muse, mutect2, varscan2
- MICALL1 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs781038559, COSV53241182; called by mutect2, varscan2
- MKNK1 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs763925172, COSV57860918; called by muse, mutect2, varscan2
- MPDZ | c.4492A>G p.S1498G | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1191820589; called by muse, mutect2, varscan2
- MYBPC1 | c.1994G>A p.R665K (on ENST00000550270 / NM_206820.2; = p.R690K on NM_002465.4) | Missense Mutation (SNP) | VAF 84/388 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100638251; called by muse, mutect2, varscan2
- NAT16 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs752502819; called by muse, mutect2, varscan2
- NCKAP5 | c.3178G>A p.D1060N | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as rs149274377, COSV100494847; called by muse, mutect2, varscan2
- NFX1 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1335097408; called by muse, mutect2, varscan2
- NPAP1 | c.1919G>A p.G640E | Missense Mutation (SNP) | VAF 16/425 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.301); catalogued as COSV61505328; called by muse, mutect2
- OR52R1 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61887913; called by muse, mutect2, varscan2
- PAPPA2 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62778463; called by muse, mutect2, varscan2
- PRDM12 | c.820C>G p.R274G | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV53391336; called by muse, mutect2, varscan2
- PRDM4 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 67/221 reads (30%) | catalogued as COSV99946338; called by muse, mutect2, varscan2
- RCE1 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as COSV100547016; called by muse, mutect2, varscan2
- RGR | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 142/648 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs767225913; called by muse, mutect2, varscan2
- RIN1 | c.1408C>A p.R470S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV100254577; called by muse, mutect2, varscan2
- RNF157 | c.1397T>A p.V466D | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV53942686; called by muse, mutect2, varscan2
- SIX5 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1249215493; called by muse, mutect2, varscan2
- SYNE1 | c.12328G>A p.D4110N (on ENST00000367255 / NM_182961.4; = p.D4039N on NM_033071.3) | Missense Mutation (SNP) | VAF 105/350 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs368462157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D2B | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 163/599 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs34324946; called by muse, mutect2, varscan2
- TDRD6 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1392094391; called by muse, mutect2
- TET2 | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866084594; called by muse, mutect2, varscan2
- TGIF2LX | c.583G>T p.V195F | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1185599182; called by muse, mutect2, varscan2
- TOM1 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65897208; called by muse, mutect2, varscan2
- TRIM58 | c.770+1G>T p.X257_splice | Splice Site (SNP) | VAF 90/425 reads (21%) | catalogued as rs748395145, COSV100825388; called by muse, mutect2, varscan2
- VPS51 | c.2045T>C p.F682S | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54209132; called by muse, mutect2, varscan2
- WASHC5 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 99/517 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV59197237; called by muse, mutect2, varscan2
- WDR20 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 97/255 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs749617951; called by muse, mutect2, varscan2
- ZBTB22 | c.1760C>A p.P587Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs757902613; called by muse, mutect2, varscan2
- ZNF536 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 78/559 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as COSV62825506; called by muse, mutect2, varscan2
- ZNF568 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 15/500 reads (3%) | SIFT tolerated (0.96); PolyPhen benign (0.167); catalogued as COSV71278654; called by muse, mutect2
- ZNF676 | c.996G>T p.K332N (on ENST00000650058; = p.K300N on NM_001001411.3) | Missense Mutation (SNP) | VAF 172/737 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1411137240, COSV68095081; called by muse, varscan2
- ACMSD | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACSM2B | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ACTL6B | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ADAMTSL3 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 85/348 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADARB1 | c.1408T>G p.Y470D | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRE3 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 261/418 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- AFG3L2 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 66/392 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- AGBL1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- ANK2 | c.1283C>A p.T428K | Missense Mutation (SNP) | VAF 153/399 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ASIC4 | c.766dup p.H256Pfs*46 | Frame Shift Ins (INS) | VAF 96/249 reads (39%) | called by mutect2, pindel, varscan2
- BBS9 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BTNL3 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, varscan2
- C10orf71 | c.2820G>T p.Q940H | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- CA2 | c.48G>C p.W16C | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAVIN1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CD5 | c.722A>C p.N241T | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CDCP2 | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CDH4 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CERCAM | c.962A>C p.E321A | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CILP | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLEC4D | c.477G>C p.Q159H | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CNTN5 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL5A2 | c.961-1G>A p.X321_splice | Splice Site (SNP) | VAF 126/442 reads (29%) | called by mutect2, varscan2
- CRYGA | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DDX10 | c.1395del p.E466Kfs*16 | Frame Shift Del (DEL) | VAF 52/179 reads (29%) | called by mutect2, pindel, varscan2
- DTHD1 | c.10G>T p.E4* (on ENST00000456874; = p.E129* on NM_001170700.3) | Nonsense Mutation (SNP) | VAF 84/228 reads (37%) | called by muse, varscan2
- DUSP8 | c.1085_1086del p.P362Hfs*26 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- ELMO1 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ENPEP | c.1793G>T p.R598M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EXD3 | c.1285G>C p.D429H | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT2 | c.5090dup p.N1698Kfs*2 | Frame Shift Ins (INS) | VAF 44/141 reads (31%) | called by mutect2, pindel, varscan2
- FBRSL1 | c.2118dup p.A707Cfs*25 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- FEZ1 | c.652A>T p.N218Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- FRMPD1 | c.1508C>A p.P503H | Missense Mutation (SNP) | VAF 75/309 reads (24%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- GOLGA8H | c.775A>G p.M259V | Missense Mutation (SNP) | VAF 138/505 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GRIN2A | c.3547C>A p.Q1183K | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCN1 | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- INPPL1 | c.2675A>G p.D892G | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ITGAD | c.2756A>T p.Y919F | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITGBL1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LGALS3BP | c.240del p.Q81Kfs*29 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- LGALS8 | c.874C>G p.H292D (on ENST00000341872; = p.H334D on NM_006499.4) | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIPA | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP6 | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAZ | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); called by muse, mutect2
- MIOS | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MRPS5 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MTMR11 | c.314G>T p.R105L (on ENST00000439741 / NM_001145862.2; = p.R33L on NM_181873.3) | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MYO9A | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NRAP | c.1957A>G p.R653G (on ENST00000359988 / NM_001322945.2; = p.R618G on NM_006175.4) | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- NTN1 | c.1216del p.C406Afs*24 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- NUTM1 | c.541G>T p.G181W | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13C3 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- OR4C46 | c.384G>T p.L128F | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL2 | c.434G>A p.W145* (on ENST00000313733 / NM_144498.4; = p.W133* on NM_014835.4) | Nonsense Mutation (SNP) | VAF 65/269 reads (24%) | called by muse, mutect2, varscan2
- PCSK1 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PDE1C | c.1839G>T p.K613N | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIK3CA | c.2995A>G p.I999V | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PLA1A | c.914C>G p.P305R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU1F1 | c.449A>G p.Q150R | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PRKCQ | c.1853C>A p.P618H | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTK2B | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PTPN18 | c.10A>G p.S4G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRQ | c.4311G>C p.K1437N (on ENST00000616559; = p.K1395N on NM_001145026.2) | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RADX | c.2023A>C p.T675P | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBP4 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 18/646 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2
- RTL9 | c.3745G>T p.V1249F | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAF8 | c.2627T>C p.I876T | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SCFD2 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SDK1 | c.2748G>C p.E916D | Missense Mutation (SNP) | VAF 34/483 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- SKAP2 | c.764C>G p.P255R | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SLC8A1 | c.1894G>T p.V632L | Missense Mutation (SNP) | VAF 103/402 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31D1 | c.1329G>C p.R443S | Missense Mutation (SNP) | VAF 138/503 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SRCIN1 | c.2921A>T p.E974V (on ENST00000621492; = p.E940V on NM_025248.3) | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SRCIN1 | c.2920G>T p.E974* (on ENST00000621492; = p.E940* on NM_025248.3) | Nonsense Mutation (SNP) | VAF 55/231 reads (24%) | called by muse, mutect2, varscan2
- STARD9 | c.1407G>T p.R469S | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- STAT6 | c.812+2T>A p.X271_splice | Splice Site (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- SYNE1 | c.23033G>T p.C7678F (on ENST00000367255 / NM_182961.4; = p.C7607F on NM_033071.3) | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SYNE1 | c.1178C>A p.T393N (on ENST00000367255 / NM_182961.4; = p.T400N on NM_033071.3) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TACC2 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TAFA5 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TAS2R1 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBX20 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 200/788 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, varscan2
- TCF12 | c.1792A>T p.K598* | Nonsense Mutation (SNP) | VAF 193/652 reads (30%) | called by muse, mutect2, varscan2
- TMEM26 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 119/503 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- TRIM49 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.049); called by muse, mutect2
- TTN | c.24909C>A p.Y8303* (on ENST00000591111; = p.Y7376* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | called by muse, mutect2, varscan2
- TXNRD3 | c.1137del p.V380Wfs*10 | Frame Shift Del (DEL) | VAF 133/530 reads (25%) | called by mutect2, pindel, varscan2
- TYR | c.755T>C p.M252T | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- UBQLN3 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UBTFL1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- UNC13C | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USF3 | c.4766A>G p.H1589R | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- USP15 | c.2828C>T p.P943L (on ENST00000280377 / NM_001351159.2; = p.P914L on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIRP2 | c.2616A>G p.I872M (on ENST00000628543; = p.I1047M on NM_152381.6) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZBTB14 | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZBTB41 | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZCCHC14 | c.366G>A p.W122* (on ENST00000268616; = p.W259* on NM_015144.3) | Nonsense Mutation (SNP) | VAF 28/158 reads (18%) | called by muse, mutect2, varscan2
- ZFHX3 | c.8843G>T p.R2948L | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM1 | c.743T>C p.I248T | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ZNF546 | c.2158C>G p.P720A | Missense Mutation (SNP) | VAF 144/234 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF780A | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 22/692 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2
- ALDH1L2 | c.2667G>C p.V889= | Silent (SNP) | VAF 106/394 reads (27%) | called by muse, mutect2, varscan2
- ALK | c.564C>A p.R188= | Silent (SNP) | VAF 141/452 reads (31%) | called by muse, mutect2, varscan2
- ANO5 | c.1605G>A p.K535= | Silent (SNP) | VAF 39/197 reads (20%) | catalogued as COSV104410040; called by muse, mutect2, varscan2
- APBA2 | c.1956C>T p.V652= | Silent (SNP) | VAF 172/626 reads (27%) | called by muse, mutect2, varscan2
- APOL2 | c.354G>T p.V118= | Silent (SNP) | VAF 69/245 reads (28%) | catalogued as rs377494811; called by muse, mutect2, varscan2
- APOO | c.141G>A p.E47= | Silent (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- CABIN1 | c.3672C>T p.T1224= | Silent (SNP) | VAF 124/466 reads (27%) | catalogued as rs748326639; called by muse, mutect2, varscan2
- CADM1 | c.570G>T p.S190= | Silent (SNP) | VAF 65/307 reads (21%) | catalogued as rs200493084; called by muse, mutect2, varscan2
- CADPS2 | c.510T>C p.A170= | Silent (SNP) | VAF 66/214 reads (31%) | called by muse, mutect2, varscan2
- CD8B | c.438G>A p.K146= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs1236954644; called by mutect2, varscan2
- CDH13 | c.729G>A p.P243= | Silent (SNP) | VAF 50/228 reads (22%) | catalogued as rs757253202, COSV51862080, COSV51874880, COSV51878630; called by muse, mutect2, varscan2
- CEACAM16 | c.969C>A p.P323= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV69186229; called by mutect2, varscan2
- CFAP46 | c.5958C>T p.G1986= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs955311264, COSV99584910; called by muse, mutect2, varscan2
- CFAP92 | c.2103C>T p.I701= | Silent (SNP) | VAF 37/323 reads (11%) | called by muse, mutect2, varscan2
- CNNM1 | c.1746G>T p.P582= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- COL4A2 | c.2241C>A p.G747= | Silent (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- CTNND2 | c.1350C>T p.T450= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs138883759, COSV58866932; called by muse, mutect2, varscan2
- DDIT4L | c.411A>G p.T137= | Silent (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- DLG1 | c.1893A>T p.P631= | Silent (SNP) | VAF 423/818 reads (52%) | catalogued as COSV58387145; called by muse, mutect2, varscan2
- DNAH5 | c.8139C>T p.R2713= | Silent (SNP) | VAF 175/555 reads (32%) | catalogued as rs1250683644; called by muse, mutect2, varscan2
- ECM1 | c.1176G>A p.R392= | Silent (SNP) | VAF 76/494 reads (15%) | called by muse, mutect2, varscan2
- EFTUD2 | c.207C>T p.A69= | Silent (SNP) | VAF 28/401 reads (7%) | catalogued as rs779021391; called by muse, mutect2
- FBXL7 | c.1227C>T p.I409= | Silent (SNP) | VAF 86/430 reads (20%) | catalogued as rs762807925, COSV61644374; called by muse, mutect2, varscan2
- FOXI3 | c.651T>C p.N217= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, varscan2
- FSIP2 | c.14139C>A p.V4713= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- FTSJ3 | c.336T>C p.D112= | Silent (SNP) | VAF 84/394 reads (21%) | called by muse, mutect2, varscan2
- GABRB1 | c.765A>G p.T255= | Silent (SNP) | VAF 57/204 reads (28%) | catalogued as rs376932728; called by muse, mutect2, varscan2
- ITPKA | c.850C>T p.L284= | Silent (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- KCNV1 | c.1062C>G p.S354= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99819029; called by muse, mutect2
- KIAA0100 | c.3879A>T p.T1293= | Silent (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- L2HGDH | c.195A>G p.R65= | Silent (SNP) | VAF 175/406 reads (43%) | catalogued as rs773869968; called by muse, mutect2, varscan2
- LAMA2 | c.2220T>A p.P740= | Silent (SNP) | VAF 59/417 reads (14%) | called by muse, mutect2, varscan2
- LDB3 | c.1482T>C p.D494= | Silent (SNP) | VAF 47/265 reads (18%) | called by muse, mutect2, varscan2
- LPO | c.1836G>T p.G612= | Silent (SNP) | VAF 67/206 reads (33%) | catalogued as COSV51856843; called by muse, mutect2, varscan2
- MROH1 | c.2805G>A p.E935= | Silent (SNP) | VAF 96/398 reads (24%) | called by muse, mutect2, varscan2
- MUC12 | c.3801C>T p.G1267= (on ENST00000379442; = p.G1124= on NM_001164462.1) | Silent (SNP) | VAF 103/686 reads (15%) | catalogued as rs1209641337; called by muse, mutect2, varscan2
- NAT2 | c.738T>C p.Y246= | Silent (SNP) | VAF 55/191 reads (29%) | catalogued as COSV99674187; called by muse, mutect2, varscan2
- NLGN1 | c.1728C>A p.T576= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- NLRP3 | c.2739G>T p.T913= | Silent (SNP) | VAF 140/398 reads (35%) | catalogued as COSV100276286; called by muse, mutect2, varscan2
- OR2A5 | c.453T>C p.C151= | Silent (SNP) | VAF 94/420 reads (22%) | catalogued as rs1187723316, COSV68738701; called by muse, mutect2, varscan2
- OR51E1 | c.805C>A p.R269= | Silent (SNP) | VAF 90/236 reads (38%) | catalogued as COSV67809719; called by muse, mutect2, varscan2
- PCDHGA8 | c.2172G>A p.L724= | Silent (SNP) | VAF 87/203 reads (43%) | called by muse, mutect2, varscan2
- PHRF1 | c.4437G>T p.P1479= (on ENST00000264555 / NM_001286581.2; = p.P1478= on NM_020901.4) | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2
- PRODH2 | c.1116G>T p.L372= (on ENST00000301175; = p.L296= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 22/622 reads (4%) | called by muse, mutect2
- SFTPB | c.912C>A p.S304= | Silent (SNP) | VAF 203/638 reads (32%) | called by muse, mutect2, varscan2
- SI | c.3351G>C p.V1117= | Silent (SNP) | VAF 100/603 reads (17%) | catalogued as COSV100016824; called by muse, mutect2, varscan2
- SLC25A13 | c.486C>T p.H162= | Silent (SNP) | VAF 65/260 reads (25%) | catalogued as rs1562831788, COSV99673663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC8A3 | c.1245C>A p.L415= | Silent (SNP) | VAF 57/327 reads (17%) | called by muse, mutect2, varscan2
- SNAP91 | c.1074T>C p.S358= | Silent (SNP) | VAF 154/413 reads (37%) | catalogued as rs1202081964; called by muse, mutect2, varscan2
- SV2C | c.66G>T p.V22= | Silent (SNP) | VAF 40/115 reads (35%) | called by muse, mutect2, varscan2
- SYT1 | c.102A>G p.E34= | Silent (SNP) | VAF 68/297 reads (23%) | catalogued as rs769666808; called by muse, mutect2, varscan2
- TAMALIN | c.723G>A p.E241= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs770827836; called by muse, mutect2, varscan2
- TNR | c.3913C>A p.R1305= | Silent (SNP) | VAF 56/371 reads (15%) | catalogued as rs778628919, COSV54896002, COSV99689299; called by muse, mutect2, varscan2
- TOPAZ1 | c.3678C>T p.C1226= | Silent (SNP) | VAF 50/129 reads (39%) | called by muse, mutect2, varscan2
- TRAV23DV6 | c.153T>C p.C51= | Silent (SNP) | VAF 61/197 reads (31%) | called by muse, mutect2, varscan2
- TRIM64B | c.75G>A p.P25= | Silent (SNP) | VAF 58/680 reads (9%) | catalogued as rs1192976298, COSV61693764, COSV61694630; called by muse, mutect2
- UNC13C | c.4491T>C p.Y1497= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2
- ZBTB18 | c.18T>C p.H6= | Silent (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2
- ZNF365 | c.769C>T p.L257= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as rs192211282; called by muse, mutect2, varscan2
- ZNF862 | c.1791G>T p.T597= | Silent (SNP) | VAF 141/537 reads (26%) | catalogued as rs1392389552, COSV56224132, COSV56224977; called by muse, mutect2, varscan2
- ZP3 | c.198C>T p.I66= (on ENST00000394857 / NM_001110354.2; = p.I15= on NM_007155.6) | Silent (SNP) | VAF 102/369 reads (28%) | catalogued as rs142032111; called by muse, mutect2, varscan2
- ABCA11P | n.1323G>A | RNA (SNP) | VAF 95/255 reads (37%) | catalogued as rs781844169; called by muse, mutect2, varscan2
- AC062028.1 | chr2:11124620 C>T | 3'Flank (SNP) | VAF 108/369 reads (29%) | catalogued as rs1025350337; called by muse, mutect2, varscan2
- ADCY10 | c.-51A>G | 5'UTR (SNP) | VAF 36/212 reads (17%) | catalogued as rs949230167; called by muse, varscan2
- ADGRD1 | c.966+1844G>C | Intron (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- AF186192.2 | n.103A>T | RNA (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- AK2 | c.*2488A>T | 3'UTR (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2
- AK7 | c.294+9C>T | Intron (SNP) | VAF 67/159 reads (42%) | catalogued as rs780706238; called by muse, mutect2, varscan2
- CSF2RA | c.*119C>T | 3'UTR (SNP) | VAF 131/309 reads (42%) | catalogued as COSV100817642; called by muse, mutect2, varscan2
- CYLC1 | c.-20G>T | 5'UTR (SNP) | VAF 54/124 reads (44%) | called by muse, varscan2
- DHRS4 | chr14:23970251 C>T | 3'Flank (SNP) | VAF 39/183 reads (21%) | called by muse, mutect2, varscan2
- FMN2 | c.-115C>A | 5'UTR (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- GPRC5A | c.981+28C>A | Intron (SNP) | VAF 86/290 reads (30%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.1176-29A>T | Intron (SNP) | VAF 75/215 reads (35%) | called by muse, mutect2, varscan2
- GYS2 | c.1891-36G>T | Intron (SNP) | VAF 60/280 reads (21%) | called by muse, mutect2, varscan2
- HSPA7 | n.415C>G | RNA (SNP) | VAF 65/171 reads (38%) | called by muse, mutect2, varscan2
- IGSF22 | c.2096-1350G>A | Intron (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- KHDC4 | c.1266+1352G>A | Intron (SNP) | VAF 101/224 reads (45%) | catalogued as rs528319814; called by muse, mutect2, varscan2
- LINC00618 | n.10G>C | RNA (SNP) | VAF 103/329 reads (31%) | called by muse, mutect2, varscan2
- MFSD14C | n.544T>C | RNA (SNP) | VAF 32/159 reads (20%) | called by muse, mutect2, varscan2
- MVK | c.*8C>A | 3'UTR (SNP) | VAF 38/419 reads (9%) | called by muse, mutect2
- NOM1 | c.1911+42C>T | Intron (SNP) | VAF 66/253 reads (26%) | called by muse, mutect2, varscan2
- OR2U1P | n.405C>T | RNA (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- P2RX1 | c.137+524T>A | Intron (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2, varscan2
- PEX19 | c.*1019C>T | 3'UTR (SNP) | VAF 15/332 reads (5%) | called by muse, mutect2
- PLEKHB2 | c.424-65645T>A | Intron (SNP) | VAF 86/321 reads (27%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.186+619G>T | Intron (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- REXO1L1P | n.1514G>C | RNA (SNP) | VAF 59/1890 reads (3%) | called by muse, mutect2
- RGS7 | c.*15T>G | 3'UTR (SNP) | VAF 49/381 reads (13%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.230+742C>G | Intron (SNP) | VAF 44/190 reads (23%) | called by muse, mutect2, varscan2
- RPN2 | chr20:37179244 G>A | 5'Flank (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- SH2D2A | c.309-20C>A | Intron (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- SLMAP | c.2022+64A>G | Intron (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2
- SSPOP | n.1180C>T | RNA (SNP) | VAF 55/227 reads (24%) | called by mutect2, varscan2
- ST20-MTHFS | c.-12+342G>A | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-119G>C | 5'UTR (SNP) | VAF 28/55 reads (51%) | catalogued as rs1277101384; called by mutect2, varscan2
- SUGT1P4-STRA6LP | n.1603G>T | RNA (SNP) | VAF 46/138 reads (33%) | called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1604G>T | RNA (SNP) | VAF 43/133 reads (32%) | called by muse, mutect2, varscan2
- TXNRD3 | n.717G>A | RNA (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- VAT1L | c.-7G>C | 5'UTR (SNP) | VAF 54/157 reads (34%) | called by muse, mutect2, varscan2
- WDR62 | c.2971+46G>T | Intron (SNP) | VAF 22/430 reads (5%) | called by muse, mutect2
